Somatic mutation profile of tumor specimen TCGA-DS-A1OD-01A (aliquot TCGA-DS-A1OD-01A-11D-A14W-08) from TCGA case TCGA-DS-A1OD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 49.2 years (17,954 days).
Specimen TCGA-DS-A1OD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cbff5de-6162-4fd1-b10a-c1ac7f75670d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A1OD-10A (Blood Derived Normal), aliquot TCGA-DS-A1OD-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afe26db1-2cf5-4975-a85c-b6158d227e62

The open-access MAF lists 62 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Frame Shift Del 2, Intron 1, RNA 1, In Frame Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1048893050, COSV58228256; called by muse, varscan2
- AFF4 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs112871745, COSV54796199; called by mutect2, varscan2
- AGAP6 | c.476G>C p.R159T (on ENST00000374056 / NM_001365867.1; = p.R182T on NM_001077665.2) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.227); catalogued as COSV65018302; called by muse, mutect2
- AGMO | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV61122133, COSV61125185; called by mutect2, varscan2
- DCAF5 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1230396454, COSV58458722; called by muse, mutect2
- DENND2C | c.1988G>A p.R663Q (on ENST00000393274 / NM_001256404.2; = p.R606Q on NM_198459.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746690091, COSV67923684; called by mutect2, varscan2
- DNAH3 | c.2006C>T p.T669M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755971290, COSV54524283; called by mutect2, varscan2
- EFCAB5 | c.4448del p.L1483Cfs*25 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV57927616; called by mutect2, pindel, varscan2
- EHBP1L1 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58574657; called by muse, mutect2, varscan2
- EIF5A | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs769669056, COSV59746693; called by muse, mutect2, varscan2
- FOXRED2 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV53400785; called by muse, mutect2
- GCC2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs915570315, COSV59173756, COSV59177754; called by muse, varscan2
- HS2ST1 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.857); catalogued as COSV59356897; called by muse, mutect2, varscan2
- ITGA2 | c.1849T>C p.Y617H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs4865757; called by mutect2, varscan2
- JHY | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759841826, COSV57074151; called by mutect2, varscan2
- KIF26B | c.2598C>G p.I866M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63649881; called by muse, mutect2, varscan2
- KIRREL2 | c.1057-2A>G p.X353_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as COSV52877805, COSV52879502; called by muse, mutect2, varscan2
- KRTAP10-1 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs782124753, COSV59956003; called by mutect2, varscan2
- LRIT3 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100015818, COSV100016110; called by mutect2, varscan2
- LRRTM3 | c.1375C>G p.R459G | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.483); catalogued as COSV63670942; called by muse, varscan2
- MARS2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456742256, COSV56570893, COSV56572225; called by muse, mutect2, varscan2
- MFHAS1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV52286290; called by mutect2, varscan2
- MUC17 | c.7651G>A p.E2551K | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60282539, COSV60286091; called by muse, mutect2, varscan2
- NCKAP1L | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762520053, COSV53204019; called by muse, mutect2, varscan2
- NOS2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs200678947; called by muse, mutect2, varscan2
- OXER1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1411030176, COSV54312760; called by muse, mutect2, varscan2
- PGD | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV54622936; called by muse, mutect2, varscan2
- POC5 | c.1649C>T p.S550L (on ENST00000428202 / NM_001099271.2; = p.S525L on NM_152408.2) | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV66842960; called by muse, mutect2, varscan2
- PRKG1 | c.1871G>A p.G624E | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV64771408; called by muse, mutect2, varscan2
- RAD54L | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58441978; called by muse, mutect2, varscan2
- RGS19 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58659173; called by muse, mutect2, varscan2
- RHCE | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as rs147526117, COSV53799581; called by muse, varscan2
- RHD | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs376674958, CM138826; called by muse, mutect2, varscan2
- RNF123 | c.2566G>T p.G856W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100246571; called by muse, mutect2, varscan2
- RNF40 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs370636384; called by muse, mutect2, varscan2
- SCAPER | c.3226G>A p.A1076T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs889208452; called by muse, mutect2, varscan2
- SEC24D | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs142063505, COSV54881321; called by muse, mutect2, varscan2
- SEPTIN6 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs770681536, COSV59716971; called by muse, mutect2, varscan2
- SH3PXD2A | c.1534C>T p.R512C (on ENST00000369774 / NM_001365079.1; = p.R484C on NM_014631.2) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs750321416, COSV60120132; called by mutect2, varscan2
- SMCHD1 | c.2104G>C p.E702Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.558); catalogued as COSV55251228, COSV55266219; called by muse, mutect2, varscan2
- SRP54 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53740509; called by muse, mutect2, varscan2
- TDRD6 | c.3666G>T p.K1222N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs1239004193; called by muse, varscan2
- TOX3 | c.99T>A p.N33K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV54872287; called by muse, mutect2, varscan2
- WBP1L | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as COSV64010269; called by muse, mutect2, varscan2
- ZNF420 | c.961C>G p.Q321E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.371); catalogued as COSV58495919; called by muse, mutect2
- AFAP1L2 | c.2038_2041del p.E680Kfs*16 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- FSIP2 | c.18293C>T p.S6098L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- REPS1 | c.241T>G p.S81A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, varscan2
- TOP2A | c.2650_2652del p.E884del | In Frame Del (DEL) | VAF 24/122 reads (20%) | called by pindel, varscan2
- AMER2 | c.1464C>G p.V488= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV63439817; called by muse, mutect2
- AP1B1 | c.432C>T p.C144= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs761252378, COSV58016932; called by muse, mutect2, varscan2
- ASPM | c.7137G>A p.Q2379= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as COSV54136908; called by muse, mutect2, varscan2
- KRTAP5-5 | c.402G>T p.G134= | Silent (SNP) | VAF 34/275 reads (12%) | catalogued as COSV68785606; called by muse, varscan2
- NOVA2 | c.510G>A p.P170= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs772334065, COSV54357098; called by mutect2, varscan2
- PCDH17 | c.1461G>A p.P487= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs548939475, COSV64978142; called by muse, varscan2
- REXO5 | c.2145G>A p.P715= | Silent (SNP) | VAF 49/285 reads (17%) | catalogued as rs748221857, COSV54471733; called by muse, varscan2
- RNF123 | c.2565A>C p.T855= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100246570; called by muse, mutect2, varscan2
- STRN | c.2274A>G p.V758= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1311602912, COSV55751478; called by muse, varscan2
- SYT10 | c.1236A>T p.R412= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV57344511; called by muse, mutect2, varscan2
- TMEM31 | c.201G>C p.T67= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100129012, COSV60328268; called by mutect2, varscan2
- AL590867.2 | n.61C>T | RNA (SNP) | VAF 18/64 reads (28%) | catalogued as rs774643256; called by muse, mutect2, varscan2
- RPE | c.342+114A>G | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs1195360425, COSV63278102; called by mutect2, varscan2
